Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HN, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HN-01A (Primary Tumor).

ICD-3
Carcinoma, Squamous cell NOS
8870/3
Site: ④ Lung, lower lobe C34.3
9/20 2/1/13

Synoptic translated report

Site : Left lung inferior lobe

☒ Central ☐ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 4.0 x 2.5 x 2.0 cm

Visceral pleural invasion: ☐ Yes ☒ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Moderately differentiated squamous cell carcinoma

Node status : N1 (1/17)

TNM : pT2a pN1 (1/17)

Pathologist signature:

Date:

Source: NCI Genomic Data Commons file 9132f5c8-8dd8-4247-a4e6-c820b9a5962a (TCGA-NC-A5HN.25D64D5A-EE0A-4772-8714-022209C35D86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).